Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9I0, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9I0-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. SPLEEN, SPLENECTOMY:
Splenic parenchyma with no significant pathologic abnormality.
- B. SOFT TISSUE, RETROPERITONEAL SARCOMA WITH TAIL OF PANCREAS,
RESECTION:
Leiomyosarcoma, FNCLCC 2/3 grade (see key pathologic findings).
- C. SOFT TISSUE, ADDITIONAL POSTERIOR MARGIN, EXCISION:
Pancreatic parenchyma and surrounding fibroadipose tissue, negative for malignancy.

KEY PATHOLOGIC FINDINGS

Tumor type:	Leiomyosarcoma
Tumor grade:	FNCLCC grade 2/3 [tumor differentiation=2, mitoses=1 and necrosis=1]
Tumor size:	18 x 15 x 13 cm (encapsulated)
Tumor involvement:	Retroperitoneum
Mitotic rate:	6 mitoses per 10 high power fields
Tumor necrosis/hyalinization:	20%
Viable tumor cells:	80%
Angiolymphatic invasion:	Absent
Surgical margins:	Free of tumor. The closest negative proximal, lateral, inferior and medial margins are less than 1 mm with a thin capsule. Final posterior margin (part C) is free of tumor.
Pathologic stage:	pT2b NX Mx
Other findings:	Spleen and pancreas are not involved by tumor

-

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Specimen(s) Received

- A. SPLEEN
B. RETROPERITONEAL SARCOMA WITH TAIL OF PANCREAS FS
C. ADDITIONAL POSTERIOR MARGIN

ICD-O-3
Leiomyosarcoma NOS 8890/3
Site: Retroperitoneum C48.0
9/24/22/14

[page 2 of 3]
Clinical History

Not given.

Preoperative Diagnosis

Leiomyosarcoma.

Intraoperative Consultation

FSB1. RETROPERITONEAL SARCOMA WITH TAIL OF PANCREAS:
Venous margin tangential, negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____, MD, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is labeled "spleen."

The specimen is received fresh and consists of a 743.1-g, 19.0 x 12.0 x 3.5 cm red-brown spleen with an intact capsule. The cut surface reveals a bright red grossly unremarkable spleen parenchyma. Sectioning of the attached adipose tissue isolates no lymph nodes.

No tissue was submitted to the _____ Representative sections are submitted as A1 and A2.

B. Specimen B is received fresh for frozen section analysis and is labeled "retroperitoneal sarcoma with tail of pancreas frozen section."

The specimen is received fresh and consists of a partially capsulated firm, gray-white, irregular bosselated mass (18.0 x 15.0 x 13.0 cm) which has been oriented by the surgeon and is inked as follows:

Proximal superior:	Black.
Inferior:	Blue.
Medial:	Red.
Lateral:	Yellow.
Anterior:	Green.
Posterior:	Orange.

The pancreatic margin of resection is stapled, measuring 5 cm in length. The staples are removed, and the underlying tissue is marked with black ink. On cross section, a portion of the pancreatic parenchyma does grossly appear to be involved with tumor. The remainder of the pancreatic parenchyma exhibits multiple cystic structures ranging from 0.5 cm to 1.0 cm in greatest dimension. The pancreatic duct is not grossly appreciated. The cut surface of the tumor consists of a soft to somewhat firm tan-pink whorled tissue with some hemorrhage and minimal necrosis (approximately

[page 3 of 3]
15%). The tangential venous margin is submitted for frozen section (FSB1).

Representative section of the tumor is submitted to the Tissue Procurement Laboratory.

Permanent representative sections are also submitted as:

- B2: Mirror image of tumor submitted to tissue bank.
- B3: Tangential pancreatic margin of resection.
- B4: Perpendicular proximal margin of resection.
- B5: Perpendicular inferior margin of resection.
- B6: Perpendicular medial margin of resection.
- B7: Perpendicular lateral margin of resection.
- B8: Perpendicular anterior margin of resection.
- B9: Perpendicular posterior margin of resection.
- B10: Perpendicular section of tumor showing its relationship to pancreas.
- B11-B20: Random representative sections of tumor.
- B21: Pancreatic cyst.
- B22: Grossly unremarkable pancreatic parenchyma.

C. Specimen C is labeled "additional posterior margin," short equals medial, long equals superior, Single equals true margin.

The specimen is received fresh and consists of a 6.0 x 4.5 x 1.0-cm soft yellow-brown irregular fragment of fibroadipose tissue. The true new posterior margin is designated by the surgeon with a single suture. This margin is entirely marked with black ink. The specimen is serially sectioned and entirely submitted as C1-C8.

Source: NCI Genomic Data Commons file 919d3526-e170-4f61-a3a1-5ee1ec17df7b (TCGA-3B-A9I0.62C0C4CE-5A2E-458D-9B97-C862CE0E219F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).